FM case AD1178 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/11a2aa81-c203-4224-96d4-c633b531cd44

Female, 62.0 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the rectum; metastasis biopsied or resected from the mediastinum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
